Somatic mutation profile of tumor specimen TCGA-DI-A2QY-01A (aliquot TCGA-DI-A2QY-01A-12D-A19Y-09) from TCGA case TCGA-DI-A2QY, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 64.1 years (23,398 days).
Specimen TCGA-DI-A2QY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8d32f555-c6a7-4d5e-af20-6cc80e1032be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DI-A2QY-11A (Solid Tissue Normal), aliquot TCGA-DI-A2QY-11A-11D-A19Y-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e7ba013d-ca78-451c-8f02-13f6b3aff393

The open-access MAF lists 107 somatic variants for this specimen: 82 protein-altering or splice-affecting, 20 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, Silent 20, Nonsense Mutation 3, Intron 3, In Frame Del 2, RNA 1, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB3 | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 100/167 reads (60%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.64); catalogued as rs1057519893, COSV57246387, COSV57246465, COSV57253558; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.827C>G p.A276G | Missense Mutation (SNP) | VAF 54/67 reads (81%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs786202082, CD098502, COSV52704969, COSV52749634, COSV52761908, COSV52834111; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCD4 | c.1086G>T p.E362D | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100084455; called by muse, mutect2, varscan2
- ABLIM3 | c.1714T>A p.Y572N | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100448646; called by muse, mutect2, varscan2
- ADRB1 | c.392G>C p.C131S | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100992301; called by muse, mutect2, varscan2
- ARHGEF3 | c.338A>T p.N113I | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.127); catalogued as COSV99575764; called by muse, mutect2, varscan2
- BAX | c.374T>C p.L125P | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV99509192; called by muse, mutect2, varscan2
- BCL6 | c.940C>G p.L314V | Missense Mutation (SNP) | VAF 23/291 reads (8%) | SIFT tolerated (0.65); PolyPhen benign (0.073); catalogued as COSV99215923; called by muse, mutect2
- CARD11 | c.446G>T p.R149L | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as COSV100712263, COSV62719866; called by muse, mutect2, varscan2
- CCAR1 | c.737C>T p.S246L | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as rs765066868, COSV99771277; called by muse, mutect2, varscan2
- CD14 | c.812G>C p.R271T | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.079); catalogued as COSV100117600; called by muse, mutect2, varscan2
- CHAF1B | c.1205A>G p.K402R | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV100023702; called by muse, mutect2
- CHRNG | c.868C>T p.L290F | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101264006; called by muse, mutect2, varscan2
- COL4A6 | c.2933G>A p.G978E | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866289854, COSV100564782; called by muse, mutect2
- COL6A2 | c.1360G>A p.G454S | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1035908319, COSV100154043; called by muse, mutect2, varscan2
- DACH1 | c.979G>A p.A327T | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.195); catalogued as rs780147904, COSV100498970; called by muse, mutect2, varscan2
- DGKA | c.647C>A p.P216Q | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV100093305; called by muse, mutect2, varscan2
- DROSHA | c.860G>T p.R287L | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.931); catalogued as COSV100757763, COSV60784683; called by muse, mutect2, varscan2
- EFEMP2 | c.245C>G p.P82R | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100337352; called by muse, mutect2, varscan2
- EPPK1 | c.5408C>T p.P1803L | Missense Mutation (SNP) | VAF 27/168 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs561337449, COSV101599921; called by muse, mutect2, varscan2
- FAM3A | c.683C>T p.T228M | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as rs782379297, COSV59194149; called by muse, mutect2, varscan2
- FAM71B | c.941C>T p.A314V | Missense Mutation (SNP) | VAF 45/92 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as rs146575394; called by muse, mutect2, varscan2
- FCGBP | c.899G>A p.R300Q | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.163); catalogued as rs566622474; called by muse, mutect2, varscan2
- FLVCR1 | c.1493G>C p.C498S | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.109); catalogued as COSV100875102; called by muse, mutect2, varscan2
- FMN2 | c.4039A>T p.T1347S | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV100146669; called by muse, mutect2, varscan2
- FUT5 | c.986A>T p.Y329F | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99398907; called by muse, mutect2, varscan2
- GLOD5 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs1557017327, COSV100297448, COSV100297516; called by muse, mutect2
- GSPT1 | c.319G>C p.E107Q (on ENST00000420576 / NM_001130007.2; = p.E245Q on NM_002094.4) | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.99); catalogued as COSV70452728; called by muse, mutect2, varscan2
- HPS5 | c.3128C>A p.P1043Q (on ENST00000349215 / NM_181507.2; = p.P929Q on NM_007216.4) | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs1455198082, COSV100752348; called by muse, mutect2
- HRH1 | c.1437C>G p.F479L | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101229092; called by muse, mutect2
- HSPG2 | c.11890G>C p.G3964R | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100760877; called by muse, mutect2, varscan2
- HYAL1 | c.864G>C p.Q288H | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV99807822; called by muse, mutect2, varscan2
- IGFN1 | c.1756G>A p.G586R (on ENST00000295591 / NM_001367841.1; = p.G3043R on NM_001164586.2) | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.749); catalogued as rs755985555, COSV99813122; called by muse, mutect2, varscan2
- INHA | c.508G>A p.G170S | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (0.63); PolyPhen benign (0.132); catalogued as COSV99217270; called by muse, mutect2, varscan2
- ITCH | c.1731G>T p.L577F (on ENST00000262650 / NM_001257137.3; = p.L536F on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV99392980; called by muse, mutect2, varscan2
- JAKMIP3 | c.1531G>A p.A511T | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1322589544, COSV100059672; called by muse, mutect2, varscan2
- KCNN2 | c.608A>G p.D203G (on ENST00000264773; = p.D415G on NM_021614.4) | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV99300389; called by muse, mutect2, varscan2
- KDM5C | c.1823G>T p.G608V | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV100949384; called by muse, mutect2, varscan2
- KPNA1 | c.832C>T p.L278F | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV60267794; called by muse, mutect2, varscan2
- LAMA1 | c.737C>G p.P246R | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV101057264; called by muse, mutect2, varscan2
- LAMC1 | c.1173C>A p.N391K | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.47); PolyPhen benign (0.062); catalogued as COSV99280206; called by muse, mutect2, varscan2
- LPGAT1 | c.641G>T p.R214M | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100878192, COSV65351402; called by muse, mutect2, varscan2
- MACO1 | c.1772G>A p.R591Q | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100975266; called by muse, mutect2, varscan2
- MAML2 | c.1044C>G p.S348R | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as COSV101594166; called by muse, mutect2
- MS4A6E | c.89C>T p.T30I | Missense Mutation (SNP) | VAF 10/123 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs367714148, COSV100279208; called by muse, mutect2
- MTRR | c.710A>G p.N237S (on ENST00000264668; = p.N210S on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as COSV99241960; called by muse, mutect2, varscan2
- NECTIN2 | c.1318T>A p.F440I | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV99375183; called by muse, mutect2, varscan2
- NEDD9 | c.2162C>G p.S721C | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV65220327; called by muse, mutect2
- NEFH | c.2638C>T p.P880S | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as COSV100151730; called by muse, varscan2
- NOL7 | c.9G>T p.Q3H | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.205); catalogued as rs201177610, COSV100702828; called by mutect2, varscan2
- NUMA1 | c.5290C>A p.P1764T | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV52621011, COSV99474897; called by muse, mutect2, varscan2
- NXF1 | c.415A>C p.I139L | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV99586296; called by muse, mutect2
- OR13A1 | c.123C>G p.Y41* | Nonsense Mutation (SNP) | VAF 8/46 reads (17%) | catalogued as COSV100981068, COSV100981073; called by muse, mutect2, varscan2
- OR4C16 | c.377A>T p.K126M | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as COSV100114211; called by muse, mutect2, varscan2
- PCSK7 | c.1569G>T p.K523N | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.023); catalogued as COSV99639159; called by muse, mutect2, varscan2
- PHYKPL | c.302C>G p.P101R | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100069647; called by muse, mutect2, varscan2
- PIK3CA | c.310C>A p.P104T | Missense Mutation (SNP) | VAF 46/66 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV55995757, COSV99081707; called by muse, mutect2, varscan2
- PPP2R1A | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 45/158 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as COSV59045141; called by muse, mutect2, varscan2
- PRPF40A | c.889C>G p.P297A | Missense Mutation (SNP) | VAF 29/168 reads (17%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.728); catalogued as COSV100582977; called by muse, mutect2, varscan2
- RFC4 | c.733C>G p.L245V | Missense Mutation (SNP) | VAF 9/201 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV104407289, COSV56215509, COSV99961308; called by muse, mutect2
- RIPK4 | c.1663G>T p.A555S (on ENST00000352483; = p.A507S on NM_020639.3) | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.955); catalogued as COSV100205231; called by muse, mutect2, varscan2
- SH3BP5 | c.527G>A p.S176N | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99508469; called by muse, mutect2
- SLC12A6 | c.671T>C p.V224A (on ENST00000354181 / NM_001365088.1; = p.V173A on NM_005135.2) | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as COSV99273028; called by muse, mutect2, varscan2
- SLC40A1 | c.460A>G p.I154V | Missense Mutation (SNP) | VAF 31/52 reads (60%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.954); catalogued as COSV99656449; called by muse, mutect2, varscan2
- SMC4 | c.3392G>A p.R1131K | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV100557549; called by muse, mutect2, varscan2
- SPATA25 | c.349G>C p.G117R | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.024); catalogued as rs913847364, COSV99510059; called by muse, mutect2, varscan2
- SPG11 | c.5730G>T p.L1910F | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99969254; called by muse, mutect2, varscan2
- ST8SIA6 | c.1175T>G p.F392C | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs191572062, COSV101112191; called by muse, mutect2, varscan2
- SYNM | c.908G>A p.G303D | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs1555483641, COSV60368899; called by muse, mutect2, varscan2
- TNXB | c.7700G>A p.S2567N (on ENST00000647633; = p.S2320N on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/191 reads (14%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.977); catalogued as rs1562815578, COSV100926508; called by muse, mutect2, varscan2
- TOP1 | c.2122C>T p.R708* | Nonsense Mutation (SNP) | VAF 59/109 reads (54%) | catalogued as COSV63692956, COSV63693268; called by muse, mutect2, varscan2
- TRIO | c.4282C>G p.R1428G | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100710752; called by muse, mutect2
- UBQLNL | c.1326G>T p.Q442H | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); catalogued as COSV100975276; called by muse, mutect2, varscan2
- VCP | c.1984C>T p.R662C | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs765795425, CM126288, COSV100734306; ClinVar: uncertain significance; called by muse, varscan2
- ZBTB7B | c.191C>G p.T64S (on ENST00000292176; = p.T98S on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as COSV99421414; called by mutect2, varscan2
- ZFYVE26 | c.5443G>C p.E1815Q | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.272); catalogued as COSV100720661; called by muse, mutect2, varscan2
- ZFYVE9 | c.2071G>T p.E691* | Nonsense Mutation (SNP) | VAF 9/28 reads (32%) | catalogued as COSV55090089, COSV99820502; called by muse, mutect2, varscan2
- AQP5 | c.445_459del p.S149_R153del | In Frame Del (DEL) | VAF 7/52 reads (13%) | called by mutect2, pindel
- CES4A | c.180_206del p.L61_P69del | In Frame Del (DEL) | VAF 13/40 reads (33%) | called by mutect2, pindel
- MAP3K10 | c.1091_1101del p.A364Dfs*22 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | called by mutect2, pindel, varscan2
- MROH1 | c.3541G>A p.A1181T | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- SGK1 | c.379A>C p.K127Q | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- ATG2B | c.3873A>G p.L1291= | Silent (SNP) | VAF 26/55 reads (47%) | catalogued as rs759799081, COSV55889277; called by muse, mutect2, varscan2
- ATP2B3 | c.2646G>A p.V882= | Silent (SNP) | VAF 34/127 reads (27%) | catalogued as COSV54862686, COSV54865077; called by muse, mutect2, varscan2
- BOD1L1 | c.4179G>T p.V1393= | Silent (SNP) | VAF 22/70 reads (31%) | catalogued as COSV50013936; called by muse, mutect2, varscan2
- CCDC66 | c.2544G>C p.P848= (on ENST00000394672 / NM_001353147.1; = p.P814= on NM_001012506.5 and 6 other RefSeq transcripts) | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV100414229; called by muse, mutect2, varscan2
- EXOC2 | c.2370G>C p.L790= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV100034021; called by muse, mutect2, varscan2
- INMT | c.717C>A p.P239= | Silent (SNP) | VAF 47/116 reads (41%) | catalogued as COSV99185113; called by muse, mutect2, varscan2
- KCNQ4 | c.600G>A p.T200= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV61273401; called by muse, mutect2
- LARGE1 | c.84C>T p.Y28= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV100506109; called by muse, mutect2, varscan2
- LOXL1 | c.1608C>T p.H536= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as rs150012543; called by muse, mutect2, varscan2
- MAT1A | c.162G>A p.V54= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as COSV64745994; called by muse, mutect2
- NEURL4 | c.651C>A p.I217= | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as rs1172158359, COSV100224528; called by muse, mutect2, varscan2
- NUMA1 | c.5289G>A p.L1763= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as COSV99474899; called by muse, mutect2, varscan2
- PBX2 | c.468C>T p.I156= | Silent (SNP) | VAF 25/158 reads (16%) | catalogued as rs372629654; called by muse, mutect2, varscan2
- PSG1 | c.357C>A p.S119= | Silent (SNP) | VAF 23/278 reads (8%) | catalogued as COSV99741042; called by muse, mutect2
- RYR2 | c.2949G>C p.L983= | Silent (SNP) | VAF 7/80 reads (9%) | catalogued as COSV100772107, COSV63688668; called by muse, mutect2
- SYT7 | c.699C>T p.D233= | Silent (SNP) | VAF 6/61 reads (10%) | catalogued as COSV55655195, COSV99801984; called by muse, mutect2, varscan2
- VPS13D | c.5508C>A p.G1836= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV99167844; called by muse, mutect2, varscan2
- ZNF208 | c.1338T>C p.I446= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV101237169; called by muse, mutect2, varscan2
- ZNF471 | c.687T>C p.T229= | Silent (SNP) | VAF 23/39 reads (59%) | catalogued as COSV100340766; called by muse, mutect2, varscan2
- ZP2 | c.2082G>A p.E694= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as COSV99559710; called by muse, mutect2, varscan2
- ANKRD20A5P | n.412C>A | RNA (SNP) | VAF 13/283 reads (5%) | called by muse, mutect2
- BGN | c.-1C>G | 5'UTR (SNP) | VAF 21/106 reads (20%) | catalogued as COSV100525260; called by muse, mutect2, varscan2
- BNC2 | c.2639+5585G>C | Intron (SNP) | VAF 14/53 reads (26%) | catalogued as COSV101034072; called by muse, mutect2, varscan2
- COP1 | c.2133+18532C>A | Intron (SNP) | VAF 15/89 reads (17%) | catalogued as COSV100443718; called by muse, mutect2, varscan2
- PTBP1 | c.892+317T>C | Intron (SNP) | VAF 8/54 reads (15%) | catalogued as COSV100608933; called by muse, mutect2, varscan2
